Somatic mutation profile of tumor specimen MP2PRT-PATVFR-TMP1-A (aliquot MP2PRT-PATVFR-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATVFR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,351 days).
Specimen MP2PRT-PATVFR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8b73c58-38e2-4519-baeb-658e9e184353.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATVFR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATVFR-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c91874d-bd0b-4927-9c5b-4936b4564fb0

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C11orf94 | c.100A>C p.R34= | Splice Region (SNP) | VAF 110/289 reads (38%) | catalogued as COSV99571423; called by muse, mutect2, varscan2
- C6orf141 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 202/610 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.825); catalogued as rs994030682; called by muse, mutect2, varscan2
- DCLK1 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs773115614, COSV55174788; called by muse, mutect2, varscan2
- DUSP26 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 131/329 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs761315485, COSV56361393; called by muse, mutect2, varscan2
- OR13C2 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs374729424; called by muse, mutect2
- PARD3B | c.2306C>T p.P769L (on ENST00000406610 / NM_001302769.2; = p.P707L on NM_152526.6) | Missense Mutation (SNP) | VAF 172/438 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377242434; called by muse, mutect2, varscan2
- PHLDB1 | c.3841G>A p.D1281N | Missense Mutation (SNP) | VAF 149/401 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535313539, COSV61882062; called by muse, mutect2, varscan2
- SPATA13 | c.1101G>A p.M367I | Missense Mutation (SNP) | VAF 15/401 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1439323626; called by muse, mutect2
- UBA2 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 23/419 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55827815; called by muse, mutect2
- WDR72 | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.283); catalogued as COSV100854073; called by muse, mutect2
- XRCC1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 135/382 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs1252949469; called by muse, mutect2
- ACTG1 | c.986T>A p.I329N | Missense Mutation (SNP) | VAF 108/362 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C2orf72 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2
- PDS5B | c.577C>G p.Q193E | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RFC3 | c.469T>G p.S157A | Missense Mutation (SNP) | VAF 163/395 reads (41%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF334 | c.893G>T p.C298F | Missense Mutation (SNP) | VAF 136/385 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ATG2B | c.3579A>C p.V1193= | Silent (SNP) | VAF 111/259 reads (43%) | called by muse, mutect2, varscan2
- MMEL1 | c.321G>A p.P107= | Silent (SNP) | VAF 206/482 reads (43%) | catalogued as rs150441473; called by muse, mutect2, varscan2
- PAPLN | c.495G>A p.S165= | Silent (SNP) | VAF 40/358 reads (11%) | catalogued as rs61742615, COSV53713702; called by muse, mutect2, varscan2
- PAX7 | c.1386C>T p.Y462= | Silent (SNP) | VAF 220/536 reads (41%) | catalogued as rs570561092, COSV64751276; called by muse, varscan2
- SLC27A6 | c.54C>T p.F18= | Silent (SNP) | VAF 42/364 reads (12%) | catalogued as COSV52483916; called by mutect2, varscan2
- UBR3 | c.117C>T p.L39= | Silent (SNP) | VAF 38/786 reads (5%) | called by muse, mutect2
